Somatic mutation profile of tumor specimen 0E0A0B from CCDI case PBCUZH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0A0B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0425c8f7-1f04-4acf-bfdf-4f74a84f1b10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0A0Q (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efee91d3-bcbb-4899-816b-a97f3087a390

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRTAP10-12 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- API5 | c.592C>T p.L198= | Silent (SNP) | VAF 149/2210 reads (7%) | called by muse, mutect2
- KMT2B | c.5073C>A p.G1691= | Silent (SNP) | VAF 38/742 reads (5%) | called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 48/1949 reads (2%) | called by muse, mutect2
